Surgical pathology report (de-identified scan), TCGA case TCGA-97-7546, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-7546-01A (Primary Tumor).

[page 1 of 4]
SPECIMENS:

1. F/S LEFT UPPER LOBE
2. COMPLETION OF LEFT UPPER LOBE
3. STATION 13 LYMPH NODE
4. LEVEL 9 LYMPH NODE
5. LEVEL 5 LYMPH NODE
6. LEVEL 7 LYMPH NODE

DIAGNOSIS:

1. LUNG, LEFT, UPPER LOBE: WEDGE RESECTION

- TWO FOCI OF INVASIVE ADENOCARCINOMA MIXED WITH BRONCHIOLOALVEOLAR CARCINOMA, RANGING FROM 2.1cm to 1.4cm, MODERATELY DIFFERENTIATED (SEE SUMMARY).
- FOCI OF ATYPICAL ALVEOLAR HYPERPLASIA.
- NO ANGIOLYMPHATIC INVASION SEEN.
- IMMUNOHISTOCHEMICAL STUDIES REVEAL THAT TUMOR CELLS ARE POSITIVE FOR CYTOKERATIN-7 AND TTF-1, BUT NEGATIVE FOR CK-20 AND CDX-2.
- MARGINS ARE NEGATIVE FOR CARCINOMA.

2. LUNG, LEFT, UPPER LOBE: LOBECTOMY

- FOCI OF ATYPICAL ALVEOLAR HYPERPLASIA.
- BRONCHIAL MARGINS ARE NEGATIVE FOR CARCINOMA.
- FOUR PERI-BRONCHIAL LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/4).

3. LYMPH NODE, STATION 13: BIOPSY

- TWO ANTHRACOTIC LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

4. LYMPH NODE, LEVEL 9: BIOPSY

- TWO ANTHRACOTIC LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

5. LYMPH NODE, LEVEL 5: BIOPSY

- THREE ANTHRACOTIC LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

6. LYMPH NODE, LEVEL 7: BIOPSY

- ONE ANTHRACOTIC LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

SUMMARY

MACROSCOPIC SUMMARY: Lung

Specimen Type: Wedge resection and lobectomy

Tumor Site: Left, Upper lobe

Tumor Locality: Multifocal

[page 2 of 4]
Tumor Greatest Dimension: 2.1 cm

MICROSCOPIC SUMMARY:

Histologic Type: Adenocarcinoma, mixed subtype with
Bronchioalveolar carcinoma
Histologic Grade: Moderately differentiated
Extent Of Invasion: Limited to pulmonary parenchyma
Margins: Uninvolved by invasive carcinoma
Blood/Lymphatic Vessel Invasion: Not observed
Venous Invasion: Not observed
Regional Lymph Nodes: N0: No regional lymph node metastasis
Nodes Examined: 12
Nodes Involved: 0
Additional Pathologic Findings: Foci of atypical alveolar
hyperplasia, Emphysematous changes

Note: This case has been reviewed intradepartmentally.

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

Lung nodule

MACROSCOPIC DESCRIPTION:

The specimen is received in six parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'left upper lobe'. It consists of an 11 x 7.5 x 3 cm lung wedge resection with a stapled margin measuring 7 cm in length. Two defects made by the surgeon are noted. The first defect measures 1.5 cm in length and the second defect measures 1.8 cm in length. The pleural surface is otherwise smooth and glistening. The surgical margin is inked black and the pleural surface is inked blue. In the first defect area, a 1.4 cm relatively well-circumscribed, tan-white, firm nodule, located 1.3 cm from the surgical margin and 0.2 cm from the pleural surface is noticed. In the second defect, a 2 x 1 cm, tan-white, firm nodule is noted. This nodule is 1.5 cm from the surgical margin and 0.2 cm from the pleura. Other areas of lung parenchyma show patchy congestion. Representative sections are submitted.

2. Part two is received in saline, labeled 'completion of left upper lobe'. It consists of a partial lobectomy measuring 18 x 7 x 3.5 cm. The specimen weighs 136 g. The specimen contains a stapled margin measuring 15 cm, which is inked in blue. After the stapled margin is removed, the underlying surface is inked in green. The pleural surface is inked in black. The specimen is serially sectioned and no

[page 3 of 4]
masses are identified. The lung parenchyma consists of tan-pink to tan-gray spongy parenchyma. Representative sections are submitted.

3. Part three is received in saline, labeled 'station 13 lymph node'. It consists of two black lymph nodes measuring 1.6 x 1.2 x 0.3 cm and 1 x 0.5 x 0.3 cm. The lymph nodes are bisected and entirely submitted in 3A.

4. Part four is received in saline, labeled 'level 9 lymph node'. It consists of two black lymph nodes, both measuring 0.8 x 0.5 x 0.2 cm. The specimen is entirely submitted.

5. Part five is received in saline, labeled 'level 5 lymph node'. It consists of three black lymph nodes ranging in size from 0.4 cm to 1.2 cm in greatest dimension. The specimen is submitted in toto.

6. Part six is received in saline, labeled 'level 7 lymph node'. It consists of one black lymph node measuring 1.2 x 0.5 x 0.5 cm. The lymph node is bisected and submitted entirely in 6A.

SUMMARY OF SECTIONS:

- 1A first nodule (frozen control)
- 1B second nodule (frozen control)
- 1C-1E first nodule
- 1F-1H second nodule
- 1I-1R representative sections including margins
- 1S unremarkable area
- 2A bronchial margin
- 2B representative section of vein with tan-brown tissue (1.2 x 0.5 x 0.4 cm)
- 2C artery margin
- 2D three hilar lymph nodes (0.5 - 1 cm, two lymph nodes inked, bisected)
- 2E-M representative sections
- 3A two lymph nodes
- 4A two lymph nodes
- 5A three lymph nodes
- 6A one lymph node

SPECIAL PROCEDURES:

CK-7, CK-20, CDX-2, TTF-1

INTRA - OPERATIVE CONSULTATION:

[page 4 of 4]
1A- Adenocarcinoma (1.4cm). 1B- Adenocarcinoma (2.1cm). Margins are free of tumor grossly.

Source: NCI Genomic Data Commons file 866025c8-9222-41dc-aae1-3f9d82381b28 (TCGA-97-7546.6D3D1827-E313-45AB-A388-406A3B26B427.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).